Somatic mutation profile of tumor specimen MMRF_2367_1_BM_CD138pos (aliquot MMRF_2367_1_BM_CD138pos_T2_KHS5U_K14017) from MMRF case MMRF_2367, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.4 years (25,729 days).
Specimen MMRF_2367_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28778b1c-9807-40da-8a70-2bf4ac4995d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2367_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2367_1_PB_Whole_C1_KHS5U_K14016; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89320602-2e3a-4c20-bb8f-7b7e826d5f29

The open-access MAF lists 119 somatic variants for this specimen: 42 protein-altering or splice-affecting, 20 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 33, Silent 20, Intron 13, 5'UTR 8, Frame Shift Del 3, 5'Flank 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 158/503 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.2119G>A p.V707M | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as rs142325682; called by muse, mutect2, varscan2
- BMPER | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs753256351, COSV51826487; called by muse, mutect2, varscan2
- ENDOU | c.378C>A p.D126E (on ENST00000422538 / NM_001172439.2; = p.D85E on NM_006025.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs144827405; called by muse, mutect2, varscan2
- GBP1 | c.1753C>G p.R585G | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs747738769; called by muse, mutect2, varscan2
- GRIN2B | c.2779C>T p.R927W | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764278787, COSV74205048; called by muse, mutect2, varscan2
- HAUS6 | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 88/131 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs763959516, COSV65840089; called by muse, mutect2, varscan2
- HIVEP3 | c.1601dup p.V535Cfs*26 | Frame Shift Ins (INS) | VAF 16/78 reads (21%) | catalogued as rs748174813; called by mutect2, varscan2
- IGLV1-51 | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs765470277; called by muse, varscan2
- NR1H4 | c.961G>T p.G321* (on ENST00000551379 / NM_001206993.2; = p.G307* on NM_005123.4) | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV51851458; called by muse, mutect2, varscan2
- PKDCC | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs763585890; called by muse, mutect2, varscan2
- PTPRB | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV100547838; called by muse, mutect2, varscan2
- SOCS1 | c.614G>C p.S205T | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.288); catalogued as COSV59660188; called by muse, mutect2, varscan2
- TLR10 | c.2291G>A p.C764Y | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as rs749057470; called by muse, mutect2, varscan2
- ZNF727 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV70702538; called by muse, mutect2, varscan2
- ZNF841 | c.1322C>T p.S441L (on ENST00000426391 / NM_001369830.1; = p.S557L on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs771279769, COSV63469857; called by muse, mutect2, varscan2
- ACOT6 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ADGRL1 | c.1082C>A p.T361N (on ENST00000340736 / NM_001008701.3; = p.T356N on NM_014921.5) | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARHGEF28 | c.3631A>G p.R1211G | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- BCAM | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.196); called by muse, varscan2
- CACNA2D1 | c.1034T>A p.L345H | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CCZ1B | c.183T>A p.N61K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- DISP2 | c.187del p.L63Wfs*102 | Frame Shift Del (DEL) | VAF 33/187 reads (18%) | called by mutect2, pindel, varscan2
- ERBB4 | c.1670C>A p.P557H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- EVC2 | c.2868G>T p.M956I | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM193A | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KMT2B | c.4004-1G>A p.X1335_splice | Splice Site (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- MORC1 | c.908T>A p.L303* | Nonsense Mutation (SNP) | VAF 38/67 reads (57%) | called by muse, mutect2, varscan2
- NAA16 | c.691+1G>A p.X231_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- NANOGNB | c.287A>C p.E96A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NPAT | c.2908del p.H970Ifs*4 | Frame Shift Del (DEL) | VAF 41/133 reads (31%) | called by mutect2, pindel, varscan2
- OVCH1 | c.2966A>C p.K989T | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SLC35G6 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TENM2 | c.3656G>A p.R1219H (on ENST00000518659 / NM_001122679.2; = p.R987H on NM_001080428.3) | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.35134G>A p.E11712K (on ENST00000591111; = p.E10785K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TYW1 | c.84T>A p.F28L | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR5 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- USP6 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.681); called by muse, mutect2
- ZDHHC5 | c.2001G>C p.K667N | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ZMPSTE24 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ZMYM2 | c.2013del p.Y671* | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- ZNF233 | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- AK5 | c.1581C>T p.P527= (on ENST00000354567 / NM_174858.3; = p.P501= on NM_012093.4) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs753733714, COSV100642658; called by muse, mutect2, varscan2
- ATG4C | c.267G>A p.L89= | Silent (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- GPHA2 | c.27G>A p.L9= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV51213623; called by muse, mutect2, varscan2
- GPRC5A | c.549C>T p.Y183= | Silent (SNP) | VAF 94/284 reads (33%) | catalogued as rs547090670; called by muse, mutect2, varscan2
- GRIK3 | c.2496G>A p.L832= | Silent (SNP) | VAF 77/192 reads (40%) | called by muse, mutect2, varscan2
- IFT140 | c.2076T>G p.V692= | Silent (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.141A>C p.S47= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs576478313; called by muse, varscan2
- IGLV1-51 | c.321C>T p.Y107= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as rs748448052; called by muse, mutect2, varscan2
- IQCA1 | c.1791C>T p.F597= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV54505722; called by muse, mutect2
- NAA15 | c.703T>C p.L235= | Silent (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- NIBAN2 | c.1344C>T p.F448= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs756098208, COSV100964991; called by muse, mutect2, varscan2
- NLRC5 | c.4020G>T p.V1340= | Silent (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- NPNT | c.936T>C p.S312= | Silent (SNP) | VAF 75/249 reads (30%) | called by muse, mutect2, varscan2
- PANX2 | c.1770C>T p.H590= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs781735267; called by muse, mutect2, varscan2
- PSMD1 | c.1965C>A p.A655= | Silent (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- RELB | c.198C>T p.F66= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs774423722; called by muse, varscan2
- SHISA9 | c.480G>A p.V160= | Silent (SNP) | VAF 52/213 reads (24%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1161G>A p.L387= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as rs749028221; called by muse, mutect2, varscan2
- SLC25A46 | c.345A>G p.V115= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- UBE2E1 | c.126C>G p.S42= | Silent (SNP) | VAF 97/420 reads (23%) | called by muse, mutect2, varscan2
- AL450336.1 | n.185A>C | RNA (SNP) | VAF 104/211 reads (49%) | called by muse, mutect2, varscan2
- ATP8A1 | c.*1176C>T | 3'UTR (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- BIRC3 | c.-112dup | 5'UTR (INS) | VAF 23/135 reads (17%) | called by mutect2, pindel, varscan2
- BLACAT1 | c.-36-7248G>A | Intron (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- CARMIL2 | c.-41T>A | 5'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- CARMIL2 | c.-40C>A | 5'UTR (SNP) | VAF 15/53 reads (28%) | catalogued as rs1419680265; called by muse, mutect2, varscan2
- CEBPA | c.*1218C>T | 3'UTR (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- CLCN4 | c.*1901C>G | 3'UTR (SNP) | VAF 35/48 reads (73%) | called by muse, mutect2, varscan2
- CSTF3 | c.-47T>C | 5'UTR (SNP) | VAF 136/379 reads (36%) | called by muse, mutect2, varscan2
- DEUP1 | c.297+174T>G | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as rs1406069280; called by muse, mutect2, varscan2
- DPP10 | c.61-147455G>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- DYNC2I1 | c.*2G>T | 3'UTR (SNP) | VAF 84/366 reads (23%) | catalogued as rs750193301; called by muse, mutect2, varscan2
- EIF1 | c.*103T>C | 3'UTR (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- F2RL1 | c.*464G>A | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- FBN2 | c.*894G>C | 3'UTR (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- GABRA2 | c.-372G>T | 5'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- GAK | c.3658-21C>T | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- GCLM | c.*2395A>G | 3'UTR (SNP) | VAF 27/85 reads (32%) | catalogued as rs575113853; called by muse, mutect2, varscan2
- GDE1 | c.*922A>C | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- GFPT2 | c.*347A>G | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- HIP1 | c.*2399C>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | catalogued as rs375420559; called by muse, mutect2
- IYD | c.*2261G>A | 3'UTR (SNP) | VAF 26/65 reads (40%) | catalogued as rs1424916497; called by muse, mutect2, varscan2
- LRFN5 | c.*79T>C | 3'UTR (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- LY6G6C | c.*317C>T | 3'UTR (SNP) | VAF 23/84 reads (27%) | catalogued as rs1464265332; called by muse, mutect2, varscan2
- MAGEB1 | c.-40C>G | 5'UTR (SNP) | VAF 58/95 reads (61%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5156G>A | Intron (SNP) | VAF 122/247 reads (49%) | catalogued as rs1377803894; called by muse, mutect2, varscan2
- MBOAT7 | c.1031+207A>T | Intron (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- MRPL50 | c.*2662C>T | 3'UTR (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1822G>A | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- NQO1 | c.-19C>A | 5'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- OSGEP | c.*445A>T | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- PATZ1 | c.1335+2003T>G | Intron (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- PDE4D | c.*3259C>A | 3'UTR (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- PDE7B | c.*1122T>G | 3'UTR (SNP) | VAF 17/43 reads (40%) | catalogued as rs901975850; called by muse, mutect2, varscan2
- PDLIM5 | c.920+1661G>A | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs532005499; called by muse, mutect2, varscan2
- RAB21 | c.*3309G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- RIMS2 | c.*2437T>C | 3'UTR (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- SAYSD1 | c.*61G>T | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- SGK1 | c.286-7603C>T | Intron (SNP) | VAF 72/251 reads (29%) | catalogued as rs1237364742; called by muse, mutect2, varscan2
- SLAMF1 | chr1:160647154 del T | 5'Flank (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- SOS1 | c.*3143_*3145del | 3'UTR (DEL) | VAF 12/39 reads (31%) | catalogued as rs779640901; called by pindel, varscan2
- SPSB4 | c.*19C>T | 3'UTR (SNP) | VAF 80/337 reads (24%) | catalogued as COSV60149232; called by muse, mutect2, varscan2
- STK17B | c.*1169A>G | 3'UTR (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- STRBP | c.*824A>C | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- TANGO2 | c.380+325G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs142088446; called by muse, mutect2, varscan2
- TBL1XR1 | c.*1029_*1031del | 3'UTR (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- TFEC | c.*220C>T | 3'UTR (SNP) | VAF 21/66 reads (32%) | catalogued as rs538685173; called by muse, mutect2, varscan2
- THAP11 | c.-110C>T | 5'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- THEMIS | c.*793dup | 3'UTR (INS) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- TMEM91 | c.361-188T>A | Intron (SNP) | VAF 5/65 reads (8%) | catalogued as rs1011495165; called by muse, mutect2
- TMSB4X | chrX:12975590 C>G | 5'Flank (SNP) | VAF 52/86 reads (60%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TNN | c.*996A>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs1023399787; called by muse, varscan2
- TRIM59 | c.*2351_*2353del | 3'UTR (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- TTC23 | c.1144-83T>C | Intron (SNP) | VAF 47/196 reads (24%) | called by muse, mutect2, varscan2
- USP7 | c.2719-82_2719-68del | Intron (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel
- ZNF704 | c.*5690T>A | 3'UTR (SNP) | VAF 30/41 reads (73%) | called by muse, mutect2, varscan2
- ZSCAN31 | c.*506A>C | 3'UTR (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
